Somatic mutation profile of tumor specimen TCGA-06-0130-01A (aliquot TCGA-06-0130-01A-01D-1490-08) from TCGA case TCGA-06-0130, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.2 years (19,812 days).
Specimen TCGA-06-0130-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e4fc4e1-5544-4d41-9bc3-e3beb402fb08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0130-10A (Blood Derived Normal), aliquot TCGA-06-0130-10A-01D-1490-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/966b6c18-c83e-4400-8b65-a6025b6dbbaa

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Nonsense Mutation 2, Splice Region 1, Splice Site 1, Frame Shift Del 1, Nonstop Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.2489+1G>T p.X830_splice | Splice Site (SNP) | VAF 18/67 reads (27%) | hotspot (GDC flag); catalogued as CS030560, CS030561, CS133197, COSV57295644, COSV57300119, COSV57302985; called by muse, mutect2, varscan2
- TP53 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 28/85 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANO9 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758562981, COSV60385574; called by muse, mutect2, varscan2
- CACNA1E | c.2295C>A p.H765Q | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV62419337; called by muse, mutect2, varscan2
- CHST5 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as rs764472163, COSV60336990; called by muse, mutect2, varscan2
- CLCN6 | c.2055G>C p.E685D | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.931); catalogued as COSV56737835; called by muse, mutect2, varscan2
- CX3CR1 | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs773508118, COSV64192959; called by muse, mutect2, varscan2
- FANCI | c.3986A>C p.*1329Sext*6 (on ENST00000310775 / NM_001376911.1; = p.*1269Sext*6 on NM_018193.3) | Nonstop Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV51519542; called by muse, mutect2, varscan2
- HELB | c.2785G>T p.E929* | Nonsense Mutation (SNP) | VAF 33/133 reads (25%) | catalogued as COSV56072057; called by muse, mutect2, varscan2
- KARS1 | c.392G>C p.R131T | Missense Mutation (SNP) | VAF 51/214 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56690637; called by muse, mutect2, varscan2
- KIAA0825 | c.854A>C p.E285A | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV56947583; called by muse, mutect2, varscan2
- MEST | c.537T>A p.G179= | Splice Region (SNP) | VAF 33/173 reads (19%) | catalogued as COSV56229800; called by muse, mutect2, varscan2
- OR2F2 | c.371T>G p.V124G | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV68833311; called by muse, mutect2, varscan2
- PTPRA | c.1408G>A p.V470M | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as rs200587047, COSV53778178; called by muse, mutect2, varscan2
- TEC | c.1631G>A p.S544N | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as rs1210858990, COSV51912390; called by muse, mutect2, varscan2
- TMEM131L | c.2068G>A p.V690I | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs369720504; called by muse, mutect2, varscan2
- TTN | c.53429G>A p.R17810H (on ENST00000591111; = p.R10386H on NM_003319.4) | Missense Mutation (SNP) | VAF 56/216 reads (26%) | PolyPhen probably damaging (0.998); catalogued as rs760068789, COSV60332466; called by muse, mutect2, varscan2
- WFDC8 | c.574A>G p.R192G | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as rs1180506309, COSV51488510, COSV51489871; called by muse, mutect2, varscan2
- ZNF578 | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101405070, COSV69737541; called by muse, mutect2, varscan2
- ZSCAN29 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs767799510, COSV53017652; called by muse, varscan2
- ARMH4 | c.656del p.N219Ifs*42 | Frame Shift Del (DEL) | VAF 37/171 reads (22%) | called by mutect2, pindel, varscan2
- KL | c.744C>A p.Y248* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- FBXO32 | c.702G>A p.L234= | Silent (SNP) | VAF 13/125 reads (10%) | catalogued as COSV54892603; called by muse, mutect2
- KIF16B | c.243C>T p.T81= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs751948015, COSV100734690, COSV61714463; called by muse, mutect2, varscan2
- LAIR1 | c.39C>T p.L13= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV57305892; called by muse, mutect2, varscan2
- SPATA31D1 | c.1788A>G p.L596= | Silent (SNP) | VAF 28/145 reads (19%) | catalogued as rs1427913012, COSV61201077; called by muse, mutect2, varscan2
- TPTE | c.441A>T p.V147= (on ENST00000618007 / NM_199261.4; = p.V129= on NM_199259.4) | Silent (SNP) | VAF 19/146 reads (13%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851580 C>T | 3'Flank (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
